Somatic mutation profile of tumor specimen TARGET-10-PATWYZ-09A (aliquot TARGET-10-PATWYZ-09A-01D) from TARGET case TARGET-10-PATWYZ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.8 years (1,385 days).
Specimen TARGET-10-PATWYZ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e5b935aa-ec59-477f-80dd-607c7e2f9db2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATWYZ-10A (Blood Derived Normal), aliquot TARGET-10-PATWYZ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c8d2988-2610-48c9-b8c1-077816266bab

The open-access MAF lists 27 somatic variants for this specimen: 14 protein-altering or splice-affecting, 9 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 9, Nonsense Mutation 2, Intron 1, 5'UTR 1, Frame Shift Del 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS18 | c.3082G>A p.E1028K | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as rs369984540; called by muse, mutect2, varscan2
- BRSK1 | c.287T>G p.L96R | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58667889; called by muse, mutect2, varscan2
- CASD1 | c.2068G>T p.G690* | Nonsense Mutation (SNP) | VAF 9/58 reads (16%) | catalogued as rs1275117563, COSV51973583; called by muse, mutect2, varscan2
- COL20A1 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs374662658; called by muse, mutect2, varscan2
- EPHA3 | c.1934A>T p.K645I | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60713556; called by muse, mutect2, varscan2
- FGFR2 | c.1292C>T p.S431L | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1483629749, COSV60651503; called by muse, mutect2, varscan2
- NOTCH1 | c.7507C>T p.Q2503* | Nonsense Mutation (SNP) | VAF 9/30 reads (30%) | catalogued as COSV53031077; called by muse, mutect2, varscan2
- NOTCH1 | c.7250C>T p.P2417L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.178); catalogued as rs370652630, COSV53025243; ClinVar: uncertain significance; called by muse, mutect2
- RBBP5 | c.745G>C p.V249L | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.906); catalogued as COSV52706353; called by muse, mutect2
- RPL10 | c.292C>A p.R98S | Missense Mutation (SNP) | VAF 11/11 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.569); catalogued as COSV50009981, COSV50010241; called by muse, mutect2, varscan2
- SOHLH1 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as rs149838416; called by mutect2, varscan2
- STXBP5L | c.2318C>A p.A773D | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV56505461, COSV56520811; called by muse, mutect2, varscan2
- TNXB | c.6100G>A p.V2034M (on ENST00000647633; = p.V1787M on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs548921928, COSV64482350; called by muse, mutect2, varscan2
- CYRIB | c.86_87del p.T29Rfs*3 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | called by mutect2, pindel
- EYS | c.2916C>T p.I972= | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as COSV65512228; called by muse, mutect2
- GRM7 | c.306C>T p.G102= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as rs765037223, COSV63137069; called by muse, mutect2, varscan2
- KRI1 | c.279G>A p.S93= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as rs774779450; called by muse, mutect2, varscan2
- PDZD2 | c.5073G>A p.S1691= | Silent (SNP) | VAF 21/135 reads (16%) | catalogued as rs200988906, COSV99227141; called by muse, mutect2, varscan2
- RELN | c.1197C>T p.S399= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as rs199686580, COSV100634984; called by muse, mutect2, varscan2
- TRIM58 | c.891C>T p.P297= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as rs745534672, COSV63572003; called by muse, mutect2, varscan2
- TUBA3C | c.468G>T p.R156= | Silent (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2
- ZDHHC5 | c.1254C>T p.F418= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as rs555991599, COSV54705729; called by muse, mutect2, varscan2
- ZNF778 | c.660C>T p.N220= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as rs761177167; called by muse, mutect2, varscan2
- BRWD1 | chr21:39314082 C>A | 5'Flank (SNP) | VAF 7/51 reads (14%) | called by muse, mutect2, varscan2
- MEIS3P2 | n.1018C>T | RNA (SNP) | VAF 13/50 reads (26%) | called by muse, mutect2, varscan2
- SNX17 | c.524-17T>G | Intron (SNP) | VAF 6/27 reads (22%) | called by muse, mutect2, varscan2
- TAS2R16 | c.-54A>T | 5'UTR (SNP) | VAF 6/14 reads (43%) | catalogued as COSV50796902; called by muse, mutect2, varscan2
